Somatic mutation profile of tumor specimen TCGA-CV-6940-01A (aliquot TCGA-CV-6940-01A-11D-1912-08) from TCGA case TCGA-CV-6940, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 80.4 years (29,382 days).
Specimen TCGA-CV-6940-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f99ee7d2-4de6-409d-ae73-01fbfd84682e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6940-10A (Blood Derived Normal), aliquot TCGA-CV-6940-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad6ef2d1-d4b9-4a61-a64a-31e7aee13770

The open-access MAF lists 138 somatic variants for this specimen: 103 protein-altering or splice-affecting, 35 silent.
By variant classification: Missense Mutation 85, Silent 35, Nonsense Mutation 13, Frame Shift Del 2, Splice Site 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 42/121 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.819_836del p.V274_G279del | In Frame Del (DEL) | VAF 21/40 reads (53%) | hotspot (GDC flag); called by mutect2, pindel
- ABCB6 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | catalogued as COSV54693512; called by muse, mutect2, varscan2
- ABCB8 | c.1933G>A p.E645K (on ENST00000297504 / NM_001282291.2; = p.E628K on NM_007188.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs749548336, COSV99874890; called by muse, mutect2, varscan2
- ABCC5 | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs756712735, COSV99657435; called by muse, mutect2, varscan2
- ACE | c.3291C>G p.Y1097* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99327608; called by muse, mutect2
- ADGRL4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs771201747, COSV66061203; called by muse, mutect2, varscan2
- AKAP12 | c.2168C>T p.T723M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs201814292, COSV53575122; called by muse, mutect2
- AL592490.1 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs1286066617, COSV69427818; called by muse, mutect2, varscan2
- APMAP | c.1169A>C p.E390A | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99468981; called by muse, mutect2, varscan2
- ARL6IP1 | c.205G>C p.G69R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100435969; called by muse, mutect2, varscan2
- ATP13A3 | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99757537; called by muse, mutect2, varscan2
- BAG4 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV99782009; called by mutect2, varscan2
- BRINP3 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100819281; called by muse, mutect2
- C21orf58 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV52451909; called by muse, mutect2, varscan2
- C2CD2 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV100298363; called by muse, mutect2, varscan2
- CALCR | c.1291C>T p.Q431* (on ENST00000649521 / NM_001164737.2; = p.Q415* on NM_001742.4) | Nonsense Mutation (SNP) | VAF 49/129 reads (38%) | catalogued as COSV100810809; called by muse, mutect2, varscan2
- CCDC39 | c.1763G>T p.R588I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99870333; called by muse, mutect2, varscan2
- CCDC57 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.596); catalogued as rs745587264, COSV100492640; called by muse, mutect2, varscan2
- CDK19 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100099120; called by muse, mutect2
- CHAD | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99366301; called by muse, mutect2, varscan2
- CHD9 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99529613; called by muse, mutect2, varscan2
- CRACDL | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as rs771059934, COSV101194119; called by muse, mutect2, varscan2
- CYP2E1 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV53315563, COSV99429185; called by muse, mutect2, varscan2
- DAG1 | c.2212G>C p.D738H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.915); catalogued as COSV58183007; called by muse, mutect2, varscan2
- DENND6A | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100231600; called by muse, mutect2, varscan2
- DHRS2 | c.743C>G p.S248* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | catalogued as COSV99160054; called by muse, mutect2, varscan2
- DHX8 | c.1994T>C p.M665T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99292560; called by muse, mutect2, varscan2
- DISP2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV99140438; called by muse, mutect2, varscan2
- DMP1 | c.336C>A p.D112E | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56820845, COSV99218982; called by muse, mutect2, varscan2
- DNAH3 | c.9736C>G p.L3246V | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54557857, COSV99767191; called by muse, mutect2, varscan2
- DOCK4 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.451); catalogued as COSV101447950; called by muse, mutect2, varscan2
- DOCK9 | c.5054G>T p.R1685M (on ENST00000376460 / NM_001366676.2; = p.R1686M on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as rs535191163, COSV100240709; called by muse, mutect2, varscan2
- ERCC6 | c.3746A>T p.D1249V | Missense Mutation (SNP) | VAF 124/223 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100876121; called by muse, mutect2, varscan2
- FAM135A | c.1037G>C p.R346T (on ENST00000370479 / NM_001351599.1; = p.R329T on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99526516; called by muse, mutect2, varscan2
- FKBP2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV100501841; called by muse, mutect2, varscan2
- FKBP2 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100501842; called by muse, mutect2, varscan2
- FRG2B | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.971); catalogued as COSV71043614; called by muse, mutect2
- FRMPD1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100899615; called by muse, mutect2, varscan2
- GBP7 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 150/213 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs1011503091, COSV99643395; called by muse, mutect2, varscan2
- GDF5 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs763209567, COSV65500436; called by muse, mutect2, varscan2
- GRHL2 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 47/115 reads (41%) | catalogued as COSV99307681; called by muse, mutect2, varscan2
- GTF3C4 | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100936070; called by muse, mutect2, varscan2
- HACL1 | c.171G>C p.M57I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100329380, COSV100329797; called by muse, mutect2, varscan2
- HPS3 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs758736477, COSV56058329; called by muse, mutect2, varscan2
- ITGA11 | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100240884, COSV100242087; called by muse, mutect2, varscan2
- ITGA7 | c.2627C>T p.S876F (on ENST00000555728; = p.S832F on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV99151561; called by muse, mutect2, varscan2
- ITPKB | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99684997; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100584164; called by muse, mutect2, varscan2
- KCNA2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316097; called by muse, mutect2, varscan2
- KDM7A | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV99135014; called by muse, mutect2, varscan2
- KRT5 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | catalogued as COSV99358239; called by muse, mutect2, varscan2
- LAMC1 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 75/121 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs752105551, COSV99280297; called by muse, mutect2, varscan2
- LIG4 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100800039; called by muse, mutect2, varscan2
- LRRC4B | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100976020; called by muse, varscan2
- MDN1 | c.5668C>T p.Q1890* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV101021738; called by muse, mutect2, varscan2
- MMP1 | c.924C>G p.F308L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100188070; called by muse, mutect2, varscan2
- MTUS1 | c.1658T>G p.L553W | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100029911; called by muse, mutect2, varscan2
- MYH8 | c.5311G>T p.E1771* | Nonsense Mutation (SNP) | VAF 38/198 reads (19%) | catalogued as COSV101238647, COSV67965659; called by muse, mutect2, varscan2
- MYO1H | c.1776C>G p.I592M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs762544542, COSV100183902; called by muse, mutect2, varscan2
- NAGA | c.298C>G p.H100D | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV101124172; called by muse, mutect2, varscan2
- NELL2 | c.2297G>C p.R766P | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.72); catalogued as COSV100420487, COSV61578031, COSV61581740; called by muse, mutect2, varscan2
- NFE2L3 | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs778619296, COSV50239794, COSV99283980; called by muse, mutect2, varscan2
- NLGN3 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as rs917449837, COSV100705005; called by muse, mutect2, varscan2
- PCCA | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV66192369; called by muse, mutect2
- PDHX | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99927867; called by muse, mutect2, varscan2
- PEG3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV55625341, COSV99690101; called by muse, mutect2, varscan2
- PEX26 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 112/331 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100299155; called by muse, mutect2, varscan2
- PLXNA3 | c.2604G>T p.L868F | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs868964336, COSV100860200; called by muse, mutect2, varscan2
- POLE | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs116326665, COSV57684709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPEF2 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372439344; called by muse, mutect2, varscan2
- PPHLN1 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as COSV99872215; called by muse, mutect2, varscan2
- RNF146 | c.224G>A p.R75Q (on ENST00000368314 / NM_001242850.2; = p.R74Q on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs146049752; called by muse, mutect2, varscan2
- SEPTIN9 | c.1046T>C p.I349T (on ENST00000427177 / NM_001113491.2; = p.I331T on NM_006640.4) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs915977873, COSV100218546; called by muse, mutect2, varscan2
- SETD5 | c.1768T>C p.S590P | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1239675222, COSV100201025; called by muse, mutect2, varscan2
- SIM1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs759405377, COSV99492425; called by muse, mutect2, varscan2
- SLC7A14 | c.1756G>T p.G586C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99200808; called by muse, mutect2, varscan2
- SMARCA2 | c.4407G>C p.K1469N | Missense Mutation (SNP) | VAF 43/638 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as COSV100190896, COSV100190956; called by muse, mutect2
- SPOCK3 | c.755C>G p.S252* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100693818; called by muse, mutect2, varscan2
- STK31 | c.2726C>G p.S909* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100669845; called by muse, mutect2
- TACR1 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | catalogued as COSV100538127; called by muse, mutect2, varscan2
- TAFA5 | c.122C>T p.A41V (on ENST00000402357 / NM_001082967.3; = p.A34V on NM_015381.7) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as COSV100385566, COSV100385982; called by muse, mutect2, varscan2
- TBC1D13 | c.885G>C p.L295F | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99804623; called by muse, mutect2, varscan2
- TBC1D9B | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100783635; called by muse, mutect2, varscan2
- TEC | c.454+2T>G p.X152_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | catalogued as COSV101202672, COSV67407017; called by muse, mutect2, varscan2
- TLE4 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV99512928; called by muse, mutect2
- TMC6 | c.2165C>T p.T722I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV100130324; called by muse, varscan2
- TMEM132D | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101399247; called by muse, mutect2, varscan2
- TTC21B | c.2543G>T p.G848V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99692747, COSV99692786; called by muse, mutect2, varscan2
- TTN | c.10720A>C p.T3574P (on ENST00000591111; = p.T3528P on NM_003319.4) | Missense Mutation (SNP) | VAF 18/148 reads (12%) | catalogued as COSV100626136; called by muse, mutect2, varscan2
- UNC5B | c.1279A>C p.K427Q | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100101223; called by muse, mutect2
- USP36 | c.7A>G p.I3V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV100361759; called by muse, mutect2, varscan2
- VPS33A | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV99931524; called by muse, mutect2, varscan2
- VPS53 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.063); catalogued as COSV99346580; called by muse, mutect2, varscan2
- WDR76 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV99776693; called by muse, mutect2, varscan2
- ZNF346 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV56155373, COSV56157551; called by muse, mutect2, varscan2
- ZNF594 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1410213162, COSV101280550; called by muse, mutect2, varscan2
- ZNFX1 | c.3010A>T p.I1004L | Missense Mutation (SNP) | VAF 126/363 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100870991; called by muse, mutect2, varscan2
- GPR179 | c.7003G>T p.E2335* (on ENST00000621958; = p.E2334* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- GTF2H4 | c.1341del p.H448Tfs*50 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- MAPK8 | c.838_839del p.F280Pfs*3 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- NRXN2 | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PRKCZ | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABRA | c.711G>A p.Q237= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs1471742223, COSV100357640; called by muse, mutect2, varscan2
- ADGRE5 | c.1033C>T p.L345= (on ENST00000242786 / NM_078481.4; = p.L252= on NM_001784.5) | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99663189; called by muse, mutect2, varscan2
- AKAP12 | c.2706A>G p.A902= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99484218; called by muse, mutect2, varscan2
- ANKRD13C | c.283C>T p.L95= | Silent (SNP) | VAF 47/65 reads (72%) | catalogued as rs773349689, COSV52029183, COSV52034652; called by muse, mutect2, varscan2
- APOL1 | c.246G>A p.Q82= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100046118, COSV100046314; called by muse, mutect2, varscan2
- CDCA2 | c.1665G>A p.K555= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs776457934, COSV100398867; called by muse, mutect2, varscan2
- CRNN | c.225G>A p.L75= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV99664321; called by muse, mutect2, varscan2
- DEFB127 | c.285G>A p.K95= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101213879; called by muse, mutect2, varscan2
- DHCR7 | c.903C>T p.H301= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV100832080; called by muse, mutect2, varscan2
- DNAJC11 | c.1374C>T p.S458= | Silent (SNP) | VAF 107/180 reads (59%) | catalogued as COSV50011776; called by muse, mutect2, varscan2
- DUOXA2 | c.540C>T p.A180= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1450178166, COSV99973458; called by muse, mutect2, varscan2
- EIF2B1 | c.714C>T p.L238= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV99434759; called by muse, mutect2, varscan2
- FBXO40 | c.462T>C p.T154= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV100573281; called by muse, mutect2, varscan2
- GFRA4 | c.28C>T p.L10= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99293958; called by muse, mutect2, varscan2
- GPC2 | c.390C>T p.Y130= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as rs774255965, COSV52787061; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1851T>C p.C617= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV100781848; called by muse, mutect2
- JMJD7-PLA2G4B | c.918C>T p.V306= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100584165; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1110C>T p.V370= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV100584167; called by muse, mutect2, varscan2
- KCNS3 | c.297C>T p.F99= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV100411378; called by muse, mutect2, varscan2
- KCNS3 | c.937C>T p.L313= | Silent (SNP) | VAF 46/156 reads (29%) | catalogued as COSV100411380; called by muse, mutect2, varscan2
- KIAA0100 | c.3567C>T p.N1189= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as rs765234379, COSV101197387; called by muse, mutect2, varscan2
- KLHL2 | c.1119C>T p.Y373= | Silent (SNP) | VAF 102/527 reads (19%) | catalogued as rs376851950; called by muse, mutect2, varscan2
- LONP2 | c.2319G>C p.L773= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV99589461; called by muse, mutect2, varscan2
- MAB21L1 | c.204C>T p.V68= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs780302682, COSV100083318; called by muse, mutect2, varscan2
- MTTP | c.2166C>T p.G722= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs770381109, COSV55511864; called by muse, mutect2, varscan2
- NOTCH1 | c.5160C>T p.A1720= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs780625273, COSV99491076; ClinVar: likely benign; called by muse, mutect2, varscan2
- OLFM3 | c.114G>T p.S38= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100129957; called by muse, mutect2, varscan2
- OR4C46 | c.726C>T p.I242= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100060924; called by muse, mutect2, varscan2
- OR4F4 | c.903T>C p.S301= | Silent (SNP) | VAF 26/340 reads (8%) | catalogued as COSV100055394; called by muse, mutect2
- OR9A4 | c.735C>T p.F245= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as COSV101516519, COSV71885913; called by muse, mutect2
- POLR3B | c.1161T>A p.I387= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99943805; called by mutect2, varscan2
- PTCH1 | c.3222C>T p.I1074= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs749448606, COSV100109694; ClinVar: likely benign; called by muse, mutect2, varscan2
- RALGPS1 | c.1314G>A p.L438= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs756938413, COSV99402389; called by muse, mutect2, varscan2
- VPS13A | c.441C>T p.I147= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100653346; called by muse, mutect2, varscan2
- WWP1 | c.903A>G p.A301= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV99617019; called by muse, mutect2, varscan2
